Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A550, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A550-01A (Primary Tumor).

Gross Description: There is a skin flap up to 10x4.5 cm in size, with pigmented mushroom-like formation up to 5 cm in its diameter, 15 mm thick.

Microscopic Description: Malignant melanoma of the skin, pigmented, with ulceration, with perifocal lymphoid infiltration. Clark level is IV. Breslow thickness is 15 mm.

Diagnosis Details: Tumor Features: Ulcerated, Tumor Extent: Reticular dermis invaded (Clark's level IV), Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin *per TSS - skin site = abdominal wall of trunk.*

Tumor size: 0 x 1.5 x 5 cm

Tumor features: Ulcerated, Pigmented

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade:

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-0-3
Melanoma, NOS 8720/3
SKIN,
Site: abdominal wall/trunk 044.5
lw
11/20/12

Qual/Correlate	☒	☐

Source: NCI Genomic Data Commons file d1065213-7ddd-4376-80bc-1724b5eb31fb (TCGA-EB-A550.3927A15E-DD1B-42A2-8B23-D9BA20D1287A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).